Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4960, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4960-01A (Primary Tumor).

[page 1 of 3]
TCGA - BP - 4960

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

with left renal mass, large.

Specimens Submitted:

1: SP: Kidney and adrenal gland, left; radical nephrectomy

2: SP: Lymph nodes, para-aortic and pre-aortic; dissection:

DIAGNOSIS:

1. SP: Kidney and adrenal gland, left; radical nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 10.5 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

2. SP: Lymph nodes, para-aortic and pre-aortic; dissection:

Lymph Nodes:

Not involved

Number of nodes examined:9

[page 2 of 3]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CD3 (Leu4)	
	CD5	
	CD20 L26	
	CD23	
	BCL2	
	NEG CONT	
	IMM RECUT	

Gross Description:

1) The specimen is received fresh, labeled "Left Kidney and Adrenal". It consists of a resected kidney with adrenal and perinephric fat measuring overall 20.5 x 13.4 x 8.5 cm and weighing 1,380 grams. There is a firm tumor mass palpated in the central zone of the kidney. The ureteral and vascular margins are free of tumor, and the margins are submitted. The specimen is bivalved to reveal a centrally located, well-circumscribed, encapsulated tumor mass measuring 10.5 x 7.5 x 5.0 cm. The cut sections of the tumor show areas that are bright yellow to tan-gray with the central portion showing tan-yellow discoloration. There are focal areas of hemorrhage and necrosis in the tumor mass. The tumor is located mostly in the lower pole, extending into the central portion of the cortex, pushing into the renal pelvis, but not grossly involving the pelvic fat. The perinephric fat adjacent to the tumor mass is inked black. The adrenal gland measures 6.5 x 1.2 x 0.5 cm and is not involved by the tumor. A portion of the tumor is submitted for TPS. The specimen is photographed. Representative sections of the tumor, adrenal gland and normal kidney are submitted.

Summary of Sections:

UM - ureteral margin
VM - vascular margin
T - tumor
TCP - center portion of the tumor which appears tan-yellow and fatty
NK - normal kidney
TWPF - tumor with pelvic fat
PFM - perinephric fat margin
ADR - adrenal

2) The specimen is received in formalin, labeled "Para-aortic and Preaortic Node". It consists of an irregular piece of tan-yellow, lobulated fatty tissue admixed with blood measuring 12.0 x 2.5 x 1.0 cm. Several tan-yellow to tan-pink lymph nodes are dissected, measuring from 0.4 up to 3.2 cm in greatest dimension. All lymph nodes are submitted.

Summary of Sections:

SS1 - serial sections of one largest lymph node
SS2 - serial sections of second largest lymph node
LNB - lymph nodes bisected
LN - lymph nodes

Summary of Sections:

Part 1: SP: Kidney and adrenal gland, left; radical nephrectomy:

Block	Sect. Site	PCs
1	adr	1

[page 3 of 3]
1	nk	1
1	pfm	1
5	t	5
2	t-cp	2
1	twnk	1
2	twpf	2
1	um	1
1	vm	1

Part 2: SP: Lymph nodes, para-aortic and pre-aortic; dissection:

Block	Sect. Site	PCs
1	ln	3
5	lnbs	10
6	ss1	6
5	ss2	5

Source: NCI Genomic Data Commons file 4251ee5e-5e5e-4006-88ef-40154fac39a8 (TCGA-BP-4960.4D054FAB-E3F8-4CBC-9468-B70EF7A82646.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).